CGCI case HTMCP-01-32-00829 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/b93cbfe7-1994-4ecd-b24f-2c7a2f304a2d

Demographics
Sex at birth: male.

Biospecimens (1 sample)
- Sample HTMCP-01-32-00829-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-32-00829-01A-01E-18168:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-32-00829-01A-01S-18168:
- % tumour top: 90
- % tumour bottom: 90
